Somatic mutation profile of tumor specimen HCM-CSHL-0080-C25-01A (aliquot HCM-CSHL-0080-C25-01A-11D-A77E-36) from HCMI case HCM-CSHL-0080-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.9 years (22,238 days).
Specimen HCM-CSHL-0080-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 350fa464-d2b8-449a-8c03-340e4d47a626.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0080-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0080-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f662962-b7a5-4c3c-a805-357be66c6f61

The open-access MAF lists 79 somatic variants for this specimen: 51 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 20, 3'UTR 4, Nonsense Mutation 4, Intron 2, In Frame Ins 2, Splice Region 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 72/610 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 27/192 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SRP72 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs387907189, CM123465; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCK1 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs766207920; called by muse, mutect2
- AP002748.5 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419343441; called by muse, mutect2
- ASTN2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1230611321, COSV99046592; called by muse, mutect2
- CADM1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs1216125604, COSV59010956; called by muse, mutect2
- CARMIL3 | c.4075C>T p.R1359W | Missense Mutation (SNP) | VAF 25/362 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs139310553; called by muse, mutect2
- CES4A | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 17/234 reads (7%) | catalogued as rs755629060; called by muse, mutect2
- CHST3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs868684674; called by muse, mutect2
- CLDN16 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374751726; called by muse, mutect2
- COL11A2 | c.1489C>T p.R497C (on ENST00000341947 / NM_080680.3; = p.R390C on NM_080679.2) | Missense Mutation (SNP) | VAF 34/433 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752552097; ClinVar: uncertain significance; called by muse, mutect2
- COL14A1 | c.5116G>A p.V1706I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs773249922, COSV52848739, COSV52851506; called by muse, mutect2, varscan2
- CRYGD | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV52205407; called by muse, mutect2, varscan2
- DDX11 | c.2638T>A p.C880S (on ENST00000545668 / NM_152438.2; = p.R831= on NM_004399.3) | Missense Mutation (SNP) | VAF 68/406 reads (17%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV52504146; called by muse, mutect2, varscan2
- DPYSL5 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56516776; called by muse, mutect2, varscan2
- FURIN | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs772432840; called by muse, mutect2
- GMPPA | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs752643023, COSV58007111; called by muse, mutect2, varscan2
- HS6ST1 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs766927296; called by muse, varscan2
- INPP4A | c.2549G>A p.R850H (on ENST00000074304 / NM_001134224.1; = p.R811H on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as rs766300586, COSV50791785; called by mutect2, varscan2
- KSR2 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as rs778353655; called by muse, mutect2, varscan2
- MAP3K3 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.553); catalogued as rs770706062; called by muse, mutect2, varscan2
- MAST1 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs759443859, COSV52242416; called by muse, mutect2
- OR5H14 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs774245498, COSV71193694; called by muse, mutect2, varscan2
- SDK1 | c.5180C>T p.P1727L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs548946940, COSV67358000; called by muse, mutect2, varscan2
- TOE1 | c.1421A>G p.N474S | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419413327; called by muse, mutect2, varscan2
- YBX1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs1462110527, COSV100172212; called by muse, mutect2
- ZNF560 | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs780300268; called by muse, mutect2, varscan2
- ZNF862 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369066632; called by muse, mutect2
- ADCY10 | c.3250G>A p.A1084T | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APOB | c.1125C>T p.S375= | Splice Region (SNP) | VAF 24/416 reads (6%) | called by muse, mutect2
- ARMCX2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- CDC42EP1 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- COL4A2 | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- EXTL3 | c.2123G>A p.W708* | Nonsense Mutation (SNP) | VAF 44/440 reads (10%) | called by muse, mutect2
- H1-7 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HTR1E | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2
- LATS1 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MCM7 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 13/261 reads (5%) | called by muse, mutect2
- MTUS1 | c.708_712dup p.A238Efs*6 | Frame Shift Ins (INS) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- NCOA6 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 17/306 reads (6%) | called by muse, mutect2
- NIPBL | c.7406A>G p.K2469R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- OR10J1 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.02); called by muse, mutect2
- OR2J3 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2
- OR5A2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SRRM2 | c.4796_4801dup p.S1600_S1601insCS | In Frame Ins (INS) | VAF 16/114 reads (14%) | called by mutect2, pindel
- TBCE | c.1319T>C p.I440T (on ENST00000366601; = p.I503T on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TMEM121 | c.575_576insACT p.L192dup | In Frame Ins (INS) | VAF 87/424 reads (21%) | called by mutect2, pindel, varscan2
- TP53 | c.856_869del p.E286Qfs*15 | Frame Shift Del (DEL) | VAF 89/558 reads (16%) | called by mutect2, pindel, varscan2
- USP17L10 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 60/372 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by mutect2, varscan2
- ZNF763 | c.392A>C p.H131P (on ENST00000358987 / NM_001367172.2; = p.H134P on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ANTXR1 | c.1137C>T p.D379= | Silent (SNP) | VAF 33/310 reads (11%) | catalogued as rs775392233, COSV58011787; called by muse, mutect2, varscan2
- ARHGEF33 | c.1761G>A p.P587= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as rs1399287312; called by muse, mutect2, varscan2
- BRINP2 | c.201C>T p.R67= | Silent (SNP) | VAF 41/252 reads (16%) | catalogued as rs138435872; called by muse, mutect2, varscan2
- DCDC1 | c.4554C>T p.S1518= (on ENST00000597505 / NM_001367979.1; = p.S625= on NM_020869.3) | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs1237416222, COSV58002645; called by muse, mutect2
- DCHS1 | c.4314C>T p.R1438= | Silent (SNP) | VAF 62/647 reads (10%) | catalogued as rs754583495, COSV55030352; called by muse, mutect2
- DES | c.312G>A p.T104= | Silent (SNP) | VAF 46/367 reads (13%) | catalogued as COSV64660606; called by muse, mutect2, varscan2
- ECT2L | c.1533G>A p.A511= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs763552266, COSV62885871; called by muse, mutect2, varscan2
- FASN | c.132C>T p.L44= | Silent (SNP) | VAF 40/730 reads (5%) | called by muse, mutect2
- KRT37 | c.285C>T p.Y95= | Silent (SNP) | VAF 32/522 reads (6%) | catalogued as rs146872723; called by muse, mutect2
- LCOR | c.3120C>T p.T1040= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- NBEA | c.249C>T p.V83= | Silent (SNP) | VAF 13/205 reads (6%) | called by muse, mutect2
- PCDHGB2 | c.2118G>A p.A706= | Silent (SNP) | VAF 35/423 reads (8%) | catalogued as COSV53951362, COSV54061452; called by muse, mutect2
- POM121L12 | c.480C>T p.P160= | Silent (SNP) | VAF 25/192 reads (13%) | catalogued as rs769352697; called by muse, mutect2, varscan2
- PROB1 | c.990C>T p.P330= | Silent (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2, varscan2
- PTPRM | c.4326C>T p.Y1442= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs777980694; called by muse, mutect2, varscan2
- SOS1 | c.483T>C p.D161= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as rs1553362598; ClinVar: likely benign; called by muse, mutect2
- SPATS2L | c.1128G>A p.A376= | Silent (SNP) | VAF 24/336 reads (7%) | catalogued as rs752637429; called by muse, mutect2
- TDP2 | c.192T>G p.P64= | Silent (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- TMEM40 | c.585C>T p.A195= | Silent (SNP) | VAF 16/219 reads (7%) | called by muse, mutect2
- XPR1 | c.1470G>A p.V490= | Silent (SNP) | VAF 36/260 reads (14%) | called by muse, mutect2, varscan2
- AFG3L2 | c.-95C>T | 5'UTR (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- CD8A | c.*167C>T | 3'UTR (SNP) | VAF 20/295 reads (7%) | called by muse, mutect2
- CPLANE1 | c.*5482G>A | 3'UTR (SNP) | VAF 15/185 reads (8%) | catalogued as rs772723784; called by muse, mutect2
- DLC1 | c.1349-17287C>T | Intron (SNP) | VAF 25/298 reads (8%) | catalogued as rs1400383849; called by muse, mutect2
- LDHA | chr11:18408066 A>G | 3'Flank (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- TMC8 | c.1252-10T>G | Intron (SNP) | VAF 42/332 reads (13%) | catalogued as rs1414247439; called by muse, mutect2, varscan2
- ZNF223 | c.*8A>G | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- ZNF714 | c.*833T>C | 3'UTR (SNP) | VAF 15/112 reads (13%) | catalogued as rs1311350639; called by muse, mutect2, varscan2
